Somatic mutation profile of tumor specimen MP2PRT-PATANU-TMP1-A (aliquot MP2PRT-PATANU-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATANU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.2 years (1,907 days).
Specimen MP2PRT-PATANU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0209162-7add-41cf-ad96-d888718a849a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATANU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATANU-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/877a8975-e808-4c89-917a-d4bace7211c7

The open-access MAF lists 26 somatic variants for this specimen: 20 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMPR1A | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 69/454 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs746231785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAND2 | c.2729G>C p.R910P (on ENST00000456430 / NM_001162499.2; = p.R817P on NM_012298.3) | Missense Mutation (SNP) | VAF 102/725 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV55988813; called by muse, mutect2, varscan2
- CERKL | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 46/318 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.066); catalogued as rs775435174, COSV59207159; called by muse, mutect2, varscan2
- CLTCL1 | c.2329G>A p.V777M | Missense Mutation (SNP) | VAF 73/450 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs555559962, COSV54233460; called by muse, mutect2, varscan2
- CPXM2 | c.974G>A p.R325H | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754686014, COSV53856331; called by muse, mutect2, varscan2
- EIF5 | c.390G>C p.M130I | Missense Mutation (SNP) | VAF 51/452 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV53687092; called by muse, mutect2, varscan2
- GJB4 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 104/804 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs748172389, COSV58356610; called by muse, mutect2
- GRM3 | c.2273C>T p.T758M | Missense Mutation (SNP) | VAF 74/455 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs141671463; called by muse, mutect2, varscan2
- OGDHL | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 79/447 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.657); catalogued as rs774547776, COSV65101494; called by muse, mutect2, varscan2
- RYR2 | c.8417G>A p.R2806H | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as rs955927781, COSV63681346; ClinVar: uncertain significance; called by muse, mutect2
- TTBK1 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 53/1091 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); catalogued as rs1383120100; called by muse, mutect2
- VPS13B | c.10539G>C p.K3513N | Missense Mutation (SNP) | VAF 12/372 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV62138001; called by muse, mutect2
- AASDH | c.3125C>G p.S1042C | Missense Mutation (SNP) | VAF 59/514 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLASP1 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 33/304 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- FRMPD1 | c.350T>C p.V117A | Missense Mutation (SNP) | VAF 47/379 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV4-61 | c.353_354insGGTTAAGG p.*119Vfs*? | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by pindel, varscan2
- IGKV1D-16 | chr2:90100734 ACCCTC>CTGAAG | Missense Mutation (ONP) | VAF 39/251 reads (16%) | called by pindel, varscan2*
- IL5RA | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 48/311 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIF21A | c.138T>G p.D46E | Missense Mutation (SNP) | VAF 44/347 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRAV8-7 | c.115A>G p.K39E | Missense Mutation (SNP) | VAF 73/373 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- ARHGEF10L | c.1455G>A p.S485= | Silent (SNP) | VAF 88/600 reads (15%) | catalogued as rs200701697, COSV51430742, COSV51433066; called by muse, mutect2, varscan2
- CEP290 | c.370T>C p.L124= | Silent (SNP) | VAF 28/252 reads (11%) | called by muse, mutect2, varscan2
- MOB3C | c.450C>A p.V150= | Silent (SNP) | VAF 68/411 reads (17%) | called by muse, mutect2, varscan2
- NCOR1 | c.1125G>A p.R375= | Silent (SNP) | VAF 15/501 reads (3%) | catalogued as rs1448050491; called by muse, mutect2
- TOR4A | c.1008G>A p.A336= | Silent (SNP) | VAF 26/819 reads (3%) | called by muse, mutect2
- IGHV1-58 | chr14:106627248 ins GACCCCC | 5'Flank (INS) | VAF 20/154 reads (13%) | called by mutect2, pindel*, varscan2
